CCDI case PBBLIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d72b2305-a0ef-40be-8474-9f6a4740e10e

Demographics
Sex at birth: male.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,975 days).

Biospecimens (3 samples)
- Sample 0DBZ53: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBZ59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBZ5E: Tissue type: Tumor; Specimen type: Solid Tissue.
